Somatic mutation profile of tumor specimen TCGA-CR-6481-01A (aliquot TCGA-CR-6481-01A-11D-1870-08) from TCGA case TCGA-CR-6481, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G2; Age at diagnosis: 47.1 years (17,203 days).
Specimen TCGA-CR-6481-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68ccb93f-a5f9-4bb5-baab-3b7115701f17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6481-10A (Blood Derived Normal), aliquot TCGA-CR-6481-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0272862b-d053-4771-b675-c4043f915150

The open-access MAF lists 516 somatic variants for this specimen: 385 protein-altering or splice-affecting, 116 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 339, Silent 116, Nonsense Mutation 36, Intron 7, Splice Site 7, 3'UTR 3, 5'Flank 2, 5'UTR 1, Translation Start Site 1, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- VPS13B | c.4471G>T p.E1491* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as rs120074151, CM041273, COSV100662200; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADAC | c.1042G>A p.D348N | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51760172; called by muse, mutect2, varscan2
- ABCB11 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99792304; called by muse, mutect2, varscan2
- ABCC6 | c.1341C>T p.L447= | Splice Region (SNP) | VAF 15/79 reads (19%) | catalogued as COSV52747807; called by muse, mutect2, varscan2
- ABCC9 | c.488C>G p.S163* | Nonsense Mutation (SNP) | VAF 34/233 reads (15%) | catalogued as COSV99685866; called by muse, mutect2, varscan2
- ABCD2 | c.1924G>A p.D642N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100429534; called by muse, mutect2
- ABCG2 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1061017, COSV52949092, COSV52949689; called by muse, mutect2, varscan2
- ADGRB2 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs767003239, COSV99926378; called by muse, mutect2, varscan2
- ADGRG5 | c.426C>G p.F142L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100446428; called by muse, mutect2, varscan2
- ADGRV1 | c.10802G>C p.R3601T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101316072; called by muse, mutect2, varscan2
- AEN | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs201760461; called by muse, mutect2
- AFF3 | c.2514G>C p.E838D | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV100419130; called by muse, mutect2, varscan2
- AGTPBP1 | c.3332G>A p.G1111E (on ENST00000357081 / NM_001330701.2; = p.G1071E on NM_015239.2) | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100429834; called by muse, mutect2, varscan2
- AKNA | c.2685C>G p.I895M | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV56315372, COSV99800478; called by muse, mutect2, varscan2
- ALKBH1 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as rs752250966, COSV99380623; called by muse, mutect2, varscan2
- ALPK3 | c.4378C>T p.L1460F | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781232591, COSV99361041; called by muse, mutect2, varscan2
- ALPK3 | c.4475C>T p.A1492V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs538810746, COSV99360990, COSV99361044; called by muse, mutect2, varscan2
- ANK3 | c.4351-1G>A p.X1451_splice (on ENST00000280772 / NM_001320874.2; = p.X576_splice on NM_001149.3) | Splice Site (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99780281; called by muse, mutect2, varscan2
- ANKRD26 | c.4411G>C p.E1471Q | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV101063250, COSV65776607; called by muse, mutect2, varscan2
- AOPEP | c.2440G>T p.V814L (on ENST00000375315 / NM_001193329.1; = p.V715L on NM_032823.5) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99949968; called by muse, varscan2
- APOD | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV58402865; called by muse, mutect2
- ARFGEF1 | c.4336G>A p.E1446K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99142570; called by muse, mutect2
- ARFGEF2 | c.5236G>C p.D1746H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100904287, COSV64213862; called by muse, mutect2, varscan2
- ARHGAP17 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.271); catalogued as COSV99253535; called by muse, mutect2, varscan2
- ARSL | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV101140584; called by muse, mutect2, varscan2
- ASB17 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 36/178 reads (20%) | catalogued as COSV99407755, COSV99407871, COSV99407958; called by muse, mutect2, varscan2
- ASXL3 | c.5020G>A p.E1674K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as rs770577167, COSV52461969, COSV99327010; called by muse, mutect2, varscan2
- ASXL3 | c.5507G>A p.G1836E | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52477534; called by muse, mutect2, varscan2
- ATAD5 | c.615G>C p.L205F | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV100429990; called by muse, varscan2
- ATAD5 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV100429991; called by muse, varscan2
- ATAD5 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as COSV100429993; called by muse, varscan2
- ATAD5 | c.1100G>C p.R367T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100429995; called by muse, varscan2
- ATAD5 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100429998; called by muse, mutect2, varscan2
- ATAD5 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100430001; called by muse, mutect2
- ATG9A | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.199); catalogued as rs1045643538, COSV99521914; called by muse, mutect2, varscan2
- ATP1B3 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs768861940, COSV53950387; called by muse, mutect2, varscan2
- ATRNL1 | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV100370936; called by muse, mutect2, varscan2
- BAIAP3 | c.3277C>T p.R1093C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.22); catalogued as rs535167017, COSV50105448; called by muse, mutect2, varscan2
- BIRC6 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 46/305 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.473); catalogued as COSV101428347; called by muse, mutect2, varscan2
- BRWD3 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.856); catalogued as COSV64743616; called by muse, mutect2, varscan2
- BRWD3 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100955674, COSV100956136; called by muse, mutect2, varscan2
- BTK | c.1939C>T p.L647F | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as CM163531, COSV100437632; called by muse, mutect2, varscan2
- BTN2A1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773258690, COSV100438625, COSV57002928; called by muse, mutect2, varscan2
- BTN3A1 | c.1503G>C p.L501F | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.855); catalogued as COSV99175844; called by muse, mutect2, varscan2
- C1S | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100196587; called by muse, mutect2, varscan2
- CALHM4 | c.838C>G p.L280V (on ENST00000368596 / NM_001366078.1; = p.L94V on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.359); catalogued as COSV100888876, COSV100888904; called by muse, mutect2, varscan2
- CAMKMT | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.184); catalogued as COSV101034864, COSV65925665; called by muse, mutect2, varscan2
- CAPN15 | c.1501G>A p.G501S | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.46); PolyPhen probably damaging (1); catalogued as COSV99562496; called by muse, mutect2, varscan2
- CAPN9 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99680516; called by muse, mutect2, varscan2
- CARMIL2 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 13/110 reads (12%) | catalogued as rs758210528, COSV58028826; called by muse, mutect2, varscan2
- CCBE1 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as rs753350074, COSV101480402, COSV71670172; called by muse, mutect2, varscan2
- CCDC181 | c.950C>G p.S317C | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as COSV100890331; called by muse, mutect2, varscan2
- CDH10 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100051721; called by muse, mutect2, varscan2
- CDH3 | c.2162G>A p.G721D | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242336678, COSV99868516; called by muse, mutect2
- CDKN3 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369886; called by muse, mutect2, varscan2
- CDSN | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1238875914, COSV99456910; called by muse, mutect2
- CEP19 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs746061097, COSV56359123, COSV99582493; called by muse, mutect2, varscan2
- CHP1 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.044); catalogued as COSV58156404; called by muse, mutect2
- CHST15 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV100655169, COSV60563370; called by muse, mutect2, varscan2
- CIT | c.2172G>C p.K724N | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99949848; called by muse, mutect2, varscan2
- CLCA1 | c.2189G>C p.R730T | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99322473; called by muse, mutect2, varscan2
- CLTA | c.628G>A p.E210K (on ENST00000242285 / NM_007096.4; = p.E180K on NM_001833.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54255037; called by muse, mutect2, varscan2
- CLUL1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs1392974454, COSV100620990; called by muse, mutect2, varscan2
- CMPK1 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 27/186 reads (15%) | catalogued as COSV100898556; called by muse, mutect2, varscan2
- CNTN5 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as rs772226535, COSV54360366; called by muse, mutect2, varscan2
- CNTN6 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100610819; called by muse, mutect2, varscan2
- COL24A1 | c.3400G>C p.G1134R | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993450; called by muse, mutect2, varscan2
- COL4A3 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.251); catalogued as rs377136253; called by muse, mutect2, varscan2
- COL4A4 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100306981, COSV61634992; called by muse, mutect2, varscan2
- COLEC10 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as rs781073829, COSV100250696; called by mutect2, varscan2
- COLGALT1 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs543254139, COSV99395097; called by muse, mutect2, varscan2
- COPZ2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV50058421, COSV99133599; called by muse, mutect2
- CREBBP | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.714); catalogued as COSV99270328; called by muse, mutect2, varscan2
- CREBRF | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV99755885; called by muse, mutect2, varscan2
- CROCC | c.4621G>A p.E1541K | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs573793650, COSV65012621; called by muse, mutect2, varscan2
- CRYBG1 | c.5326G>A p.E1776K | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1020229596, COSV100954490; called by muse, varscan2
- CRYZL1 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs752772127, COSV99280983; called by muse, mutect2, varscan2
- CTSW | c.831C>G p.I277M | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.262); catalogued as COSV100327167; called by muse, mutect2, varscan2
- CUX1 | c.2264C>G p.S755C | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV99471746; called by muse, mutect2, varscan2
- CYP4A11 | c.1352C>G p.S451* | Nonsense Mutation (SNP) | VAF 70/404 reads (17%) | catalogued as COSV100152430; called by muse, mutect2, varscan2
- DDR1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1477583730, COSV61324964; called by muse, mutect2
- DDX6 | c.685C>A p.L229I | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.791); catalogued as COSV99870419; called by muse, varscan2
- DIDO1 | c.3061G>A p.D1021N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs571096023, COSV99826030; called by muse, mutect2, varscan2
- DIDO1 | c.2959G>A p.D987N | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.395); catalogued as COSV56633964, COSV99826032; called by muse, mutect2, varscan2
- DLG5 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.758); catalogued as rs747244996, COSV64947815; called by muse, mutect2, varscan2
- DMXL2 | c.4549C>T p.H1517Y | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99196427; called by muse, mutect2, varscan2
- DNAJB13 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as COSV100334508, COSV60271303; called by muse, mutect2, varscan2
- DNAJC1 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV100978015; called by muse, mutect2, varscan2
- DNAJC22 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV67712686; called by muse, mutect2, varscan2
- DNM1L | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99846139; called by muse, mutect2, varscan2
- DOK2 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs368473444; called by mutect2, varscan2
- DOK5 | c.410-1G>C p.X137_splice | Splice Site (SNP) | VAF 6/85 reads (7%) | catalogued as COSV99374039; called by muse, mutect2
- DSP | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs397516943, BM1344445, COSV101131255, COSV65793658; called by muse, mutect2, varscan2
- DSP | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | catalogued as COSV101131327; called by muse, mutect2, varscan2
- DUSP16 | c.1925C>T p.S642L | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99963176; called by muse, mutect2, varscan2
- DUSP19 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV100700282; called by muse, mutect2, varscan2
- DUSP19 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100700283; called by muse, mutect2, varscan2
- DUSP7 | c.942C>G p.I314M | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99623502; called by muse, mutect2, varscan2
- DYRK4 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99156554; called by muse, mutect2, varscan2
- E2F6 | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs1168981860, COSV100215346; called by muse, mutect2, varscan2
- EHMT2 | c.1350G>C p.E450D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.124); catalogued as rs547949077, COSV100977205; called by muse, mutect2, varscan2
- EIF3A | c.3343G>A p.D1115N | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.322); catalogued as COSV100974637; called by muse, varscan2
- EIF4G1 | c.3979G>A p.E1327K (on ENST00000346169 / NM_198241.3; = p.E1132K on NM_004953.5) | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100071903; called by muse, mutect2, varscan2
- EPHA3 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 19/162 reads (12%) | catalogued as COSV100345724; called by muse, mutect2, varscan2
- ERBB4 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99624864; called by muse, mutect2, varscan2
- ERP27 | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99844329; called by muse, mutect2, varscan2
- ERP44 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV99316465; called by muse, mutect2
- ETF1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.254); catalogued as COSV100860183; called by muse, mutect2, varscan2
- ETV5 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1221002517, COSV100112340; called by muse, mutect2
- ETV6 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV56766737; called by muse, mutect2, varscan2
- EXOC4 | c.1007+1G>A p.X336_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99554229; called by muse, mutect2
- F13B | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.338); catalogued as COSV100803310; called by mutect2, varscan2
- FAM102B | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.95); catalogued as rs1382498039, COSV100899287; called by muse, mutect2, varscan2
- FAM118A | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1310765976, COSV99343593; called by muse, mutect2, varscan2
- FAM166A | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1185981887, COSV100457997; called by muse, mutect2, varscan2
- FANCA | c.429G>C p.K143N | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as COSV101224851; called by muse, varscan2
- FANCM | c.554G>C p.R185T | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431701664, COSV99360960; called by muse, varscan2
- FANCM | c.2495C>G p.S832C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV99951103; called by muse, mutect2, varscan2
- FAT2 | c.11425C>T p.L3809F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV55814637, COSV55818269; called by muse, mutect2, varscan2
- FBN2 | c.4603G>C p.E1535Q | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52539266, COSV99327968; called by muse, mutect2, varscan2
- FBXO17 | c.534G>C p.Q178H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV99494137; called by muse, mutect2, varscan2
- FBXO21 | c.357G>C p.K119N | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100401760; called by muse, mutect2, varscan2
- FCRL3 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs764039332, COSV100943283; called by muse, mutect2
- FCRL3 | c.1050G>C p.E350D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as COSV100943285, COSV63845530; called by muse, mutect2, varscan2
- FN3KRP | c.59C>A p.S20* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs770978856, COSV53930344, COSV99485021; called by muse, mutect2, varscan2
- FNDC3A | c.2371G>A p.E791K (on ENST00000492622 / NM_001079673.2; = p.E735K on NM_014923.5) | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV68133678; called by muse, mutect2, varscan2
- FNIP2 | c.2392G>C p.D798H | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV100032744; called by muse, mutect2
- FRAS1 | c.4195G>C p.D1399H | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV53623302, COSV99352653; called by muse, mutect2, varscan2
- G6PC3 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as rs373207529; called by muse, mutect2, varscan2
- GABRA3 | c.878C>G p.S293* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100942825; called by muse, mutect2, varscan2
- GABRB1 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs539587921, COSV54996293; called by muse, mutect2, varscan2
- GADL1 | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV56978972, COSV99244470; called by muse, mutect2, varscan2
- GAPDHS | c.509C>G p.T170R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99722349; called by muse, mutect2, varscan2
- GBA2 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100803402; called by muse, mutect2, varscan2
- GBA2 | c.597G>C p.Q199H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV100803403; called by muse, mutect2
- GDF15 | c.39G>C p.Q13H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99416176; called by muse, mutect2
- GDNF | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV100427470, COSV58480456, COSV58482133; called by muse, mutect2, varscan2
- GGA3 | c.1052C>T p.S351L (on ENST00000537686 / NM_138619.4; = p.S318L on NM_014001.5) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99822105; called by muse, mutect2, varscan2
- GIGYF2 | c.1697C>G p.S566C | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101004401; called by muse, mutect2, varscan2
- GRHL1 | c.1668G>C p.L556F | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61408076; called by muse, mutect2, varscan2
- GRIA3 | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.257); catalogued as COSV99990418, COSV99991660; called by muse, mutect2, varscan2
- GRIN2A | c.1326C>G p.I442M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as COSV100410051, COSV58028398; called by muse, mutect2, varscan2
- GTF3C1 | c.3961C>T p.R1321C | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754481582, COSV100649457; called by muse, mutect2, varscan2
- H3C11 | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 33/129 reads (26%) | catalogued as COSV100137920; called by muse, mutect2, varscan2
- HDAC7 | c.2500G>A p.A834T (on ENST00000427332; = p.A873T on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as rs748469796, COSV99316315; called by muse, mutect2, varscan2
- HDHD5 | c.304G>A p.E102K (on ENST00000336737 / NM_033070.3; = p.E72K on NM_017829.5) | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV99324794; called by muse, mutect2, varscan2
- HEATR4 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1226385081, COSV100620403; called by muse, mutect2, varscan2
- HELZ | c.2216C>T p.P739L | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV100698770; called by muse, mutect2, varscan2
- HEMK1 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as COSV51749794; called by muse, mutect2
- HEPACAM2 | c.814G>A p.A272T (on ENST00000394468 / NM_001039372.4; = p.A260T on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506593; called by muse, mutect2, varscan2
- HERC2 | c.10411G>C p.E3471Q | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.475); catalogued as COSV99874246; called by muse, mutect2, varscan2
- HK2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.38); catalogued as COSV99309124; called by muse, mutect2, varscan2
- HMGA2 | c.305C>G p.S102* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV101328978; called by muse, mutect2, varscan2
- HNRNPCL1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs540095399, COSV58613157; called by muse, mutect2, varscan2
- HOXB8 | c.539C>G p.S180W | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99494089; called by muse, mutect2, varscan2
- HPN | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV52884722, COSV99385149; called by muse, mutect2, varscan2
- HSP90B1 | c.1775C>G p.A592G | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs762366467, COSV100236569; called by muse, mutect2
- HSPA5 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.012); catalogued as COSV99413429; called by muse, mutect2, varscan2
- HTRA4 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV56758140; called by muse, mutect2
- ICOS | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100320357, COSV57030016; called by muse, mutect2, varscan2
- IFNGR1 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 15/101 reads (15%) | catalogued as COSV100880493; called by muse, mutect2, varscan2
- IFT172 | c.2012C>A p.S671Y | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV99562599; called by muse, mutect2, varscan2
- IL16 | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs774501000, COSV100267652; called by muse, mutect2, varscan2
- ITIH2 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs375764473; called by muse, mutect2, varscan2
- ITSN1 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.445); catalogued as rs373408649; called by muse, mutect2, varscan2
- KAT7 | c.712C>G p.H238D | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV99371805; called by muse, mutect2, varscan2
- KCNB2 | c.2525G>A p.R842K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.031); catalogued as COSV101578807; called by muse, mutect2, varscan2
- KCNC2 | c.1793C>T p.S598F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV54363545; called by muse, mutect2
- KCNH1 | c.2806G>A p.D936N (on ENST00000271751 / NM_172362.3; = p.D909N on NM_002238.4) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV55069744; called by muse, mutect2, varscan2
- KCNH3 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1486180019, COSV57789775; called by muse, mutect2, varscan2
- KIAA1109 | c.4594C>T p.R1532C | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52688572; called by muse, mutect2, varscan2
- KIF14 | c.4363G>C p.E1455Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66263648; called by muse, mutect2
- KIF2C | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100945733; called by muse, mutect2, varscan2
- KIF4B | c.459C>A p.C153* | Nonsense Mutation (SNP) | VAF 23/183 reads (13%) | catalogued as COSV101469301; called by muse, mutect2, varscan2
- KLHL24 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.375); catalogued as rs763143836, COSV99664955; called by muse, mutect2
- KLHL4 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100909665; called by muse, mutect2, varscan2
- KMT5C | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV55319861; called by muse, mutect2, varscan2
- KPNA2 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100388788; called by muse, mutect2, varscan2
- KPNA2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs1391419820, COSV100388789; called by muse, mutect2, varscan2
- LAMC2 | c.3225G>C p.Q1075H | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs766785221, COSV99917522; called by muse, mutect2, varscan2
- LAP3 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV99884343; called by muse, mutect2, varscan2
- LBP | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs1223982939, COSV54143314; called by muse, mutect2, varscan2
- LCLAT1 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100092694; called by muse, mutect2
- LIMD2 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99368614; called by muse, mutect2, varscan2
- LIPE | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV99734153; called by muse, mutect2, varscan2
- LLGL2 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV99388661, COSV99389867; called by muse, mutect2, varscan2
- LMBRD2 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV99682893; called by muse, mutect2, varscan2
- LMTK3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV99540583; called by muse, mutect2, varscan2
- LOXL2 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs774665129, COSV66691205; called by muse, mutect2, varscan2
- LOXL2 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV101207914; called by muse, mutect2, varscan2
- LRIT1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV100928093; called by muse, mutect2, varscan2
- LRIT3 | c.1718G>A p.R573K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV100016154; called by muse, mutect2, varscan2
- LRPPRC | c.4060C>G p.L1354V | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs1010859859, COSV99580772; called by muse, mutect2, varscan2
- LRRC37B | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs764460487, COSV58951172; called by muse, mutect2, varscan2
- LYST | c.7600C>T p.Q2534* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV101089634; called by muse, mutect2, varscan2
- LYST | c.6673C>T p.R2225C | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.792); catalogued as rs375665715; called by muse, mutect2, varscan2
- MACF1 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV100484795; called by muse, mutect2, varscan2
- MAP10 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); catalogued as COSV101406513; called by muse, mutect2, varscan2
- MAP1A | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100288718; called by muse, mutect2, varscan2
- MAPKBP1 | c.1943G>C p.G648A (on ENST00000456763 / NM_001128608.2; = p.G642A on NM_014994.3) | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV52960382, COSV99529589; called by muse, mutect2, varscan2
- MAST4 | c.3878C>T p.S1293L (on ENST00000403625 / NM_001164664.2; = p.S1104L on NM_015183.3) | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371063642; called by muse, mutect2, varscan2
- MDN1 | c.2197G>C p.E733Q | Missense Mutation (SNP) | VAF 4/83 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV101021423; called by muse, mutect2
- ME3 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs372905882; called by muse, mutect2, varscan2
- MECOM | c.678C>G p.F226L (on ENST00000468789 / NM_001105078.4; = p.F414L on NM_004991.4) | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99244811; called by muse, mutect2
- MFSD6L | c.1486C>T p.R496* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs746197361, COSV61688412; called by muse, mutect2, varscan2
- MIS12 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99342355; called by muse, mutect2, varscan2
- MME | c.1172G>C p.R391T | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100852416; called by muse, mutect2, varscan2
- MMUT | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV99222361; called by muse, varscan2
- MON1A | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223683634, COSV56559784; called by mutect2, varscan2
- MTAP | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV101205465; called by muse, mutect2, varscan2
- MTCL1 | c.2971G>C p.E991Q (on ENST00000306329 / NM_001378206.1; = p.E672Q on NM_015210.4) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.396); catalogued as COSV100094722; called by muse, varscan2
- MTCL1 | c.3069G>C p.K1023N (on ENST00000306329 / NM_001378206.1; = p.K704N on NM_015210.4) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV60412590; called by muse, varscan2
- MTUS1 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV100029502; called by muse, mutect2, varscan2
- MYH14 | c.3637G>A p.E1213K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV99222929; called by muse, mutect2, varscan2
- MYLK | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV100659167, COSV60609252; called by muse, mutect2, varscan2
- NBAS | c.5263G>A p.D1755N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV99870008, COSV99870112; called by muse, mutect2, varscan2
- NCALD | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.254); catalogued as rs530185576, COSV99637311; called by muse, mutect2, varscan2
- NCOR1 | c.5533G>A p.E1845K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV51973819, COSV51986045; called by muse, mutect2, varscan2
- NCS1 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969936; called by muse, mutect2, varscan2
- NEK9 | c.1799G>A p.R600H | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs200363570, COSV99464139; called by muse, mutect2, varscan2
- NELFB | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV100546914; called by muse, mutect2, varscan2
- NEU2 | c.408G>A p.W136* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99290588; called by muse, mutect2, varscan2
- NIN | c.5369G>A p.R1790Q (on ENST00000382041 / NM_182946.1; = p.R1077Q on NM_016350.4) | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs369558417; called by muse, mutect2, varscan2
- NLK | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as COSV69411640; called by muse, mutect2, varscan2
- NMI | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV54638726; called by muse, mutect2
- NONO | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99338894; called by muse, mutect2, varscan2
- NPAS3 | c.679G>A p.E227K (on ENST00000356141 / NM_001164749.2; = p.E195K on NM_022123.3) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as COSV100388100; called by muse, mutect2, varscan2
- NPR2 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100438929; called by muse, mutect2, varscan2
- NRCAM | c.2624G>A p.R875Q (on ENST00000379028 / NM_001371124.1; = p.R859Q on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.506); catalogued as rs1487445946, COSV100694800; called by muse, mutect2, varscan2
- NSD1 | c.4465G>A p.D1489N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV100729262; called by muse, mutect2, varscan2
- NTM | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as COSV100867549; called by muse, mutect2, varscan2
- NTNG2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.428); catalogued as rs758318272, COSV100647493; called by muse, mutect2, varscan2
- NUDCD1 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.129); catalogued as COSV99516830, COSV99517222; called by muse, mutect2, varscan2
- NUP50 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1427507798, COSV100754354; called by muse, mutect2, varscan2
- OR2M4 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100141271; called by muse, mutect2
- OR4F6 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs558260972, COSV100186931; called by muse, mutect2, varscan2
- OSMR | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1401483552, COSV99953223; called by muse, mutect2
- PAK2 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100506154; called by muse, mutect2
- PARP8 | c.1428+1G>A p.X476_splice | Splice Site (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99891446; called by muse, mutect2, varscan2
- PCBP4 | c.812C>T p.S271L (on ENST00000322099 / NM_033010.2; = p.S228L on NM_020418.4) | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100437044; called by muse, mutect2, varscan2
- PCDHA6 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100972323, COSV65352615; called by muse, mutect2, varscan2
- PDCD11 | c.3730G>A p.E1244K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs765758017, COSV63933926; called by muse, mutect2, varscan2
- PHRF1 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99200892; called by muse, varscan2
- PIDD1 | c.1533G>C p.E511D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.815); catalogued as COSV100204217; called by muse, mutect2, varscan2
- PIGR | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100732526; called by muse, mutect2, varscan2
- PKD1L2 | c.2534C>G p.S845C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100216661; called by muse, mutect2, varscan2
- PKD2L2 | c.1695G>A p.M565I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as COSV50364141; called by muse, mutect2
- PKP4 | c.2925-1G>A p.X975_splice | Splice Site (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100733858; called by muse, mutect2, varscan2
- PLEKHA6 | c.3031G>A p.V1011M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV99692164; called by muse, varscan2
- PLK3 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100221180; called by muse, mutect2, varscan2
- PMFBP1 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52821075, COSV52832018, COSV99400974; called by muse, mutect2, varscan2
- PNMA8A | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs1337183385, COSV100562337; called by muse, mutect2, varscan2
- PNMT | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99510632; called by muse, mutect2, varscan2
- PNO1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV99721498; called by muse, mutect2, varscan2
- POLR3A | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV100965676, COSV64930771; called by muse, mutect2, varscan2
- POLR3GL | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV100996814; called by muse, mutect2, varscan2
- PPFIA3 | c.3437C>G p.S1146* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as COSV53255221, COSV99417994; called by muse, mutect2
- PPP2R1B | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100232205; called by muse, mutect2, varscan2
- PRB3 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 62/553 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1272187269, COSV99685795; called by muse, varscan2
- PREX2 | c.4177C>G p.Q1393E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV99907634, COSV99910968; called by muse, mutect2, varscan2
- PRF1 | c.1457A>T p.D486V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772313460, COSV100942624; called by muse, mutect2, varscan2
- PRKACB | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV100853946, COSV65759508; called by muse, mutect2, varscan2
- PRKCA | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV99434864; called by muse, mutect2, varscan2
- PROM2 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100469049; called by muse, mutect2
- PROSER1 | c.808C>G p.P270A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100612829, COSV61489803; called by muse, mutect2, varscan2
- PRPS1L1 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs1451564948, COSV101552939; called by muse, mutect2, varscan2
- PSMB10 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99863088; called by muse, mutect2, varscan2
- PTCH1 | c.1023G>C p.L341F | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59461906; called by muse, mutect2, varscan2
- PWP1 | c.732G>C p.K244N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.852); catalogued as COSV101338820, COSV69833225; called by muse, mutect2, varscan2
- QARS1 | c.1813C>G p.Q605E | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV100070060; called by muse, mutect2, varscan2
- QSOX1 | c.1388C>G p.S463C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100852908, COSV62581758; called by muse, mutect2, varscan2
- RAB6B | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as rs147187493, COSV53315537; called by muse, mutect2, varscan2
- RAD17 | c.70G>C p.D24H (on ENST00000380774 / NM_133339.2; = p.D13H on NM_002873.1) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV99281532; called by muse, mutect2, varscan2
- RAD17 | c.235G>C p.E79Q (on ENST00000380774 / NM_133339.2; = p.E68Q on NM_002873.1) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.091); catalogued as COSV99281534; called by muse, mutect2
- RAD21 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 30/190 reads (16%) | catalogued as COSV99815199; called by muse, varscan2
- RALGAPA1 | c.3328G>A p.D1110N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99354973; called by muse, mutect2, varscan2
- RAPGEF6 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV99726648; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1697C>A p.S566Y | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99228858; called by muse, mutect2, varscan2
- RBM25 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV56200285, COSV99998752; called by muse, mutect2, varscan2
- RBM26 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99936217; called by muse, mutect2, varscan2
- RCC1L | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1043483704; called by muse, mutect2, varscan2
- RGL1 | c.695C>T p.S232L (on ENST00000360851 / NM_001297672.2; = p.S267L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100486948; called by muse, mutect2, varscan2
- RGS16 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1355549333, COSV100842487; called by muse, mutect2, varscan2
- RGS4 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100905579; called by muse, mutect2, varscan2
- RNF113A | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV101007059; called by muse, mutect2
- RNF150 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV100153555, COSV60789568; called by muse, varscan2
- RNF2 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV100835661, COSV100835748; called by muse, mutect2
- RNF213 | c.8378C>G p.S2793* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100300692; called by muse, mutect2, varscan2
- ROCK2 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99837465; called by muse, mutect2, varscan2
- RP1L1 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs375440665; called by muse, mutect2, varscan2
- RPF1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1462596978, COSV101039769; called by muse, mutect2, varscan2
- RPS13 | c.55C>G p.R19G | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV57180427; called by muse, mutect2, varscan2
- RUNX3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1424371682, COSV100136917; called by muse, mutect2, varscan2
- RXFP3 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs138975968, COSV100347578; called by muse, mutect2, varscan2
- S100A4 | c.142-1G>A p.X48_splice | Splice Site (SNP) | VAF 31/155 reads (20%) | catalogued as COSV62876717; called by muse, mutect2, varscan2
- SAMD7 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs758690200, COSV59417753; called by muse, mutect2, varscan2
- SBNO1 | c.2545G>A p.E849K (on ENST00000420886; = p.E848K on NM_018183.5) | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.453); catalogued as COSV99929279; called by muse, mutect2, varscan2
- SBNO1 | c.1921G>A p.E641K (on ENST00000420886; = p.E640K on NM_018183.5) | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV99929281; called by muse, varscan2
- SCN3A | c.1203G>A p.M401I | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV51820241; called by muse, mutect2, varscan2
- SCN5A | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1419003529, COSV100348719; called by muse, mutect2
- SCN7A | c.5020G>T p.E1674* | Nonsense Mutation (SNP) | VAF 44/255 reads (17%) | catalogued as COSV101313248, COSV69270986; called by muse, mutect2
- SDHC | c.386G>A p.W129* | Nonsense Mutation (SNP) | VAF 24/175 reads (14%) | catalogued as COSV100713689; called by muse, mutect2, varscan2
- SENP5 | c.1729C>G p.L577V | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100052057; called by muse, mutect2, varscan2
- SEPTIN12 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | catalogued as COSV99190722; called by muse, mutect2
- SFRP1 | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV99617422; called by muse, mutect2, varscan2
- SLC22A4 | c.1610C>T p.S537L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV99569411; called by muse, mutect2
- SLC25A45 | c.93G>C p.Q31H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99587324; called by muse, mutect2, varscan2
- SLC30A8 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101438535; called by muse, mutect2, varscan2
- SLC35G1 | c.448G>A p.A150T (on ENST00000427197 / NM_001134658.3; = p.A149T on NM_153226.4) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs776196137, COSV101004080; called by muse, mutect2, varscan2
- SLC39A12 | c.270A>T p.E90D | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV101070070; called by muse, mutect2, varscan2
- SLC39A6 | c.2240A>T p.H747L | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99309636; called by muse, mutect2, varscan2
- SLC4A9 | c.1759G>C p.D587H (on ENST00000507527 / NM_001258428.2; = p.D563H on NM_031467.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99138993; called by muse, varscan2
- SMARCD3 | c.1224C>G p.F408L (on ENST00000262188 / NM_001003801.2; = p.F395L on NM_003078.4) | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99223104; called by muse, mutect2, varscan2
- SOAT1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1180193439, COSV100858976; called by muse, mutect2, varscan2
- SOCS5 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.988); catalogued as rs768070642, COSV100125284; called by muse, mutect2, varscan2
- SPATC1 | c.1437G>C p.K479N | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101085012; called by muse, mutect2, varscan2
- SPTAN1 | c.6474G>C p.K2158N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100823633; called by mutect2, varscan2
- SPTBN1 | c.5173G>A p.E1725K | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100442750; called by muse, mutect2, varscan2
- SRRM2 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 20/244 reads (8%) | catalogued as COSV100070906; called by muse, mutect2
- ST13 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99344225, COSV99344478; called by muse, mutect2, varscan2
- STAT2 | c.2339G>A p.G780E | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99950671; called by muse, mutect2
- STEAP2 | c.975G>C p.M325I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.506); catalogued as COSV99840455; called by muse, mutect2
- STYXL2 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54803804, COSV99609341; called by muse, mutect2, varscan2
- STYXL2 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99609344; called by muse, mutect2, varscan2
- TARBP2 | c.145G>A p.D49N (on ENST00000266987 / NM_134323.2; = p.D28N on NM_004178.4) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV99908526; called by muse, mutect2, varscan2
- TBC1D9B | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100783537; called by muse, mutect2, varscan2
- TBX10 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100039764; called by muse, mutect2, varscan2
- TGM5 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as COSV55008405, COSV99589022; called by muse, mutect2
- THAP11 | c.538C>G p.P180A | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.158); catalogued as COSV99534442; called by muse, varscan2
- THAP11 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99534443; called by muse, varscan2
- THAP2 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100350489; called by muse, mutect2, varscan2
- THSD4 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as COSV55986842, COSV99965786; called by muse, mutect2, varscan2
- TLK2 | c.135G>C p.L45F | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.934); catalogued as COSV100409267; called by muse, mutect2, varscan2
- TMCC1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV100261081, COSV100261156; called by muse, mutect2, varscan2
- TMEM132D | c.3186G>T p.R1062S | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV101242879; called by muse, mutect2, varscan2
- TMEM132D | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV70602594; called by muse, mutect2, varscan2
- TMEM266 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV101189623; called by muse, mutect2, varscan2
- TNFAIP3 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.024); catalogued as COSV52798638; called by muse, mutect2
- TNIP2 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs1158295108, COSV100198677; called by muse, mutect2, varscan2
- TNRC6C | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as COSV100050063; called by muse, mutect2, varscan2
- TNS1 | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50698983, COSV99410886; called by muse, mutect2
- TNXB | c.4288G>A p.E1430K (on ENST00000647633; = p.E1183K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.784); catalogued as rs781061300, COSV100926391; called by muse, mutect2
- TP53BP2 | c.1006G>A p.D336N (on ENST00000343537 / NM_001031685.3; = p.D207N on NM_005426.2) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.996); catalogued as COSV100636665; called by muse, mutect2, varscan2
- TPR | c.3001C>T p.Q1001* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as COSV100823975; called by muse, mutect2, varscan2
- TRIM14 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV100419589; called by muse, mutect2, varscan2
- TRPM1 | c.2988G>A p.W996* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as COSV56640089, COSV99856038; called by muse, mutect2, varscan2
- TSR3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.038); catalogued as COSV99136258; called by muse, varscan2
- TTC37 | c.2751C>G p.F917L | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV100706673, COSV62454925; called by muse, mutect2
- TTN | c.32095G>A p.E10699K (on ENST00000591111; = p.E9772K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/273 reads (13%) | PolyPhen benign (0); catalogued as rs188482293; called by muse, mutect2, varscan2
- UHRF1 | c.298G>C p.G100R (on ENST00000612630 / NM_001290050.1; = p.G113R on NM_013282.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.439); catalogued as COSV99503549; called by muse, mutect2, varscan2
- UHRF1BP1 | c.4041G>A p.M1347I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760538566, COSV99511958; called by muse, mutect2, varscan2
- ULK4 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs774107813, COSV57209180; called by muse, mutect2, varscan2
- USP29 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.871); catalogued as rs754319159, COSV99518167; called by mutect2, varscan2
- USP32 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.6); catalogued as COSV100342112, COSV56278882; called by muse, mutect2, varscan2
- VAMP5 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.845); catalogued as rs375756032; called by muse, mutect2, varscan2
- VAV2 | c.2620G>A p.E874K (on ENST00000371850 / NM_001134398.2; = p.E835K on NM_003371.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867276571, COSV100573462; called by muse, mutect2, varscan2
- VIM | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99813129; called by muse, mutect2, varscan2
- WDSUB1 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99714114; called by muse, mutect2, varscan2
- WEE2 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.209); catalogued as rs772202171, COSV66878191; called by muse, mutect2, varscan2
- ZMYM1 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.127); catalogued as COSV100720997; called by muse, mutect2, varscan2
- ZNF124 | c.177G>C p.Q59H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100517804; called by muse, mutect2, varscan2
- ZNF19 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV99867370; called by muse, mutect2
- ZNF217 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 17/120 reads (14%) | catalogued as rs780850297, COSV100184502; called by muse, mutect2, varscan2
- ZNF33A | c.964G>A p.D322N (on ENST00000458705 / NM_006974.3; = p.D323N on NM_006954.2) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV100275869, COSV56725459; called by muse, mutect2, varscan2
- ZNF536 | c.2345C>T p.P782L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225379710, COSV62833390; called by muse, mutect2, varscan2
- ZNF554 | c.1017G>C p.L339F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.902); catalogued as COSV57885735; called by muse, mutect2, varscan2
- ZNF554 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100421219, COSV57887106; called by muse, mutect2, varscan2
- ZNF563 | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.974); catalogued as rs868091481, COSV53370060; called by muse, mutect2, varscan2
- ZNF570 | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100356191, COSV57580034; called by muse, mutect2, varscan2
- ZNF627 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs1193768469, COSV63142224; called by muse, mutect2
- ZNF682 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1228233257, COSV100653271; called by muse, mutect2, varscan2
- ZNF704 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.317); catalogued as rs375392857; called by muse, mutect2, varscan2
- ZNF713 | c.836G>A p.G279E (on ENST00000633730 / NM_001366796.2; = p.G292E on NM_182633.3) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.061); catalogued as COSV101448737; called by muse, mutect2, varscan2
- ZNF750 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs377565207, COSV53961393, COSV53961753; called by muse, mutect2, varscan2
- ZNF750 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 16/84 reads (19%) | catalogued as COSV53960359; called by muse, mutect2, varscan2
- ZNF768 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV99411447, COSV99411461; called by muse, mutect2, varscan2
- ZNF804A | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV100168229; called by muse, mutect2, varscan2
- ZNF816 | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99554593; called by muse, varscan2
- ZP2 | c.1337C>T p.T446M | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs190038226, COSV54816046; called by muse, mutect2, varscan2
- ZSWIM2 | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV99720265; called by muse, mutect2, varscan2
- ARAP3 | c.3722G>T p.G1241V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR13J1 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PNPLA8 | c.1207-1G>A p.X403_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- PSG3 | c.293_295delinsAA p.R98Qfs*11 | Frame Shift Del (DEL) | VAF 59/619 reads (10%) | called by pindel, varscan2*
- A4GNT | c.762C>T p.F254= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs369495396; called by muse, mutect2, varscan2
- AASDH | c.426C>T p.F142= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99221340; called by muse, mutect2, varscan2
- ABCA4 | c.180G>C p.A60= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs756647171, CD1311055, COSV100933139, COSV64670879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.1896C>T p.I632= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV101239409; called by muse, mutect2, varscan2
- AOX1 | c.2988C>T p.F996= | Silent (SNP) | VAF 17/180 reads (9%) | catalogued as COSV101022020; called by muse, mutect2
- ATAD5 | c.1032G>A p.L344= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100429992; called by muse, varscan2
- ATAD5 | c.1173G>A p.V391= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100429996; called by muse, varscan2
- ATM | c.372C>T p.I124= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs773495195, COSV99589869; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP13A4 | c.981G>A p.K327= | Silent (SNP) | VAF 17/173 reads (10%) | catalogued as rs1437929967, COSV99794612; called by muse, mutect2, varscan2
- BCO2 | c.891C>T p.F297= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100730364; called by muse, varscan2
- C19orf44 | c.189C>G p.L63= | Silent (SNP) | VAF 27/226 reads (12%) | catalogued as COSV99522211; called by muse, mutect2, varscan2
- CARD14 | c.309C>T p.V103= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs746855162, COSV100712568; called by muse, mutect2, varscan2
- CASZ1 | c.3978G>A p.R1326= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100681513; called by muse, mutect2, varscan2
- CBLIF | c.762C>G p.L254= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99950969; called by muse, mutect2, varscan2
- CCDC97 | c.921C>T p.D307= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs143105404; called by muse, mutect2, varscan2
- CLASP2 | c.3345G>A p.L1115= (on ENST00000359576; = p.L1114= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV100223549, COSV56287741; called by muse, mutect2, varscan2
- CNTNAP5 | c.21G>A p.L7= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV101420720; called by muse, mutect2
- CSF1 | c.1182C>G p.L394= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV100294561; called by muse, mutect2, varscan2
- CTSW | c.432C>T p.I144= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs1314230693, COSV100327388; called by muse, mutect2, varscan2
- CUX2 | c.3291G>A p.L1097= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs749091563, COSV99919837; called by muse, mutect2, varscan2
- CWH43 | c.1539G>T p.V513= | Silent (SNP) | VAF 40/260 reads (15%) | catalogued as COSV99893512; called by muse, varscan2
- DNAH11 | c.8148C>T p.V2716= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100179426; called by muse, mutect2, varscan2
- DSP | c.1620C>T p.L540= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV65793586; called by muse, varscan2
- EEF1AKMT4-ECE2 | c.1135C>A p.R379= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as COSV100668642, COSV62570884; called by muse, varscan2
- EP400 | c.3666C>T p.L1222= | Silent (SNP) | VAF 14/109 reads (13%) | catalogued as COSV100201333; called by muse, mutect2, varscan2
- EPDR1 | c.540C>A p.T180= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99554451; called by muse, mutect2
- EPPK1 | c.5424C>T p.D1808= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV101599861; called by muse, mutect2, varscan2
- ERC2 | c.1422C>G p.L474= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs1043057419, COSV99885530; called by muse, mutect2, varscan2
- ERICH3 | c.3066C>A p.A1022= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV100444549, COSV58620443; called by muse, mutect2, varscan2
- EYA4 | c.609G>A p.K203= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100765958, COSV62056255; called by muse, mutect2, varscan2
- FAM181A | c.312G>A p.Q104= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99967897; called by muse, mutect2, varscan2
- FANCM | c.5640C>T p.F1880= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV57496783; called by muse, mutect2, varscan2
- FBXL4 | c.1278C>T p.C426= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100014155; called by muse, mutect2, varscan2
- FCHO1 | c.156G>A p.A52= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs148025294, COSV53181905; called by muse, mutect2, varscan2
- FOXE1 | c.348C>G p.R116= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100909938, COSV100909999; called by muse, mutect2, varscan2
- FZD8 | c.1245G>A p.V415= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV101020239; called by muse, mutect2, varscan2
- GGA1 | c.1644G>A p.L548= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100289762; called by muse, mutect2
- GOLGA3 | c.3351G>A p.E1117= | Silent (SNP) | VAF 33/200 reads (17%) | catalogued as COSV99207285; called by muse, mutect2, varscan2
- GOLPH3L | c.369G>A p.L123= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV55047214; called by muse, mutect2, varscan2
- H2AC6 | c.237C>T p.I79= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as rs747391112, COSV100019926; called by muse, mutect2, varscan2
- HERC2 | c.6324C>T p.L2108= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs769445863, COSV55319185; called by muse, mutect2, varscan2
- IGKV1D-16 | c.291C>T p.I97= | Silent (SNP) | VAF 25/245 reads (10%) | catalogued as rs1253915196; called by muse, mutect2, varscan2
- IGSF1 | c.2613C>T p.F871= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100812114; called by muse, mutect2, varscan2
- ITPR3 | c.7503C>T p.F2501= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV100952006; called by muse, mutect2, varscan2
- KAZN | c.1137G>A p.K379= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as rs1280110745, COSV100747889; called by muse, mutect2
- KNG1 | c.792C>T p.C264= | Silent (SNP) | VAF 24/163 reads (15%) | catalogued as rs201943382, COSV53980470; called by muse, mutect2, varscan2
- LRRC37B | c.1152G>A p.L384= | Silent (SNP) | VAF 34/239 reads (14%) | catalogued as COSV100496299; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2757C>A p.L919= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99169218; called by muse, mutect2, varscan2
- MAST4 | c.5106C>T p.L1702= (on ENST00000403625 / NM_001164664.2; = p.L1513= on NM_015183.3) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99844423; called by muse, mutect2, varscan2
- MLLT6 | c.2175G>C p.A725= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- MPP4 | c.393G>A p.Q131= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as rs1195610530, COSV100206948; called by muse, mutect2, varscan2
- MS4A6E | c.369G>C p.L123= | Silent (SNP) | VAF 29/221 reads (13%) | catalogued as COSV100279161; called by muse, mutect2, varscan2
- MTCH1 | c.1002C>T p.L334= (on ENST00000373627 / NM_001271641.1; = p.L317= on NM_014341.2) | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV101010185; called by muse, mutect2, varscan2
- MYBBP1A | c.477G>C p.S159= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99626195; called by mutect2, varscan2
- MYT1L | c.1803C>T p.R601= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs753714812, COSV67720014; called by mutect2, varscan2
- NAT16 | c.456G>T p.P152= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100296293; called by muse, mutect2, varscan2
- NMS | c.363C>T p.F121= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100966604; called by muse, mutect2, varscan2
- NMT1 | c.459C>G p.P153= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99364821; called by muse, mutect2, varscan2
- NOTCH1 | c.7068C>T p.A2356= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs1248005744, COSV99488551; called by muse, mutect2, varscan2
- NR3C2 | c.471G>A p.V157= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as COSV60999105; called by muse, mutect2, varscan2
- NUTM1 | c.2484C>T p.T828= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs137916466; called by muse, mutect2, varscan2
- NWD1 | c.2400C>A p.L800= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100342772, COSV60339595; called by muse, mutect2, varscan2
- OR1L3 | c.621G>A p.V207= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV100506257, COSV100506307; called by muse, mutect2, varscan2
- PCDHA1 | c.2103C>T p.I701= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV65376858; called by muse, mutect2, varscan2
- PCDHGA6 | c.936G>C p.S312= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as COSV53925407, COSV99539435; called by muse, mutect2, varscan2
- PCK1 | c.1143C>T p.V381= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100100549; called by muse, mutect2, varscan2
- PEMT | c.579C>T p.S193= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs758030412, COSV99703144; called by mutect2, varscan2
- PHKA2 | c.960C>A p.L320= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV101177112; called by muse, mutect2, varscan2
- PKHD1L1 | c.9594G>C p.V3198= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV101006225; called by muse, mutect2
- PLCH1 | c.4170C>G p.L1390= (on ENST00000340059 / NM_001130960.2; = p.L1382= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV100397048; called by muse, mutect2
- PLEKHG3 | c.696C>G p.L232= (on ENST00000394691; = p.L288= on NM_001308147.2) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99906663; called by muse, mutect2
- PLOD2 | c.1887C>T p.F629= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV99282834; called by muse, mutect2, varscan2
- PPIP5K1 | c.3582C>T p.F1194= (on ENST00000396923; = p.F1169= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV100288719; called by muse, mutect2, varscan2
- PPP4R4 | c.291C>T p.V97= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100175740; called by mutect2, varscan2
- PRG4 | c.885G>A p.Q295= | Silent (SNP) | VAF 32/219 reads (15%) | catalogued as COSV100825793; called by muse, mutect2, varscan2
- PSMD2 | c.1458C>T p.G486= | Silent (SNP) | VAF 56/212 reads (26%) | catalogued as rs1443357860, COSV100031806; called by muse, mutect2, varscan2
- PTK7 | c.744C>T p.F248= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100030231; called by muse, mutect2
- PTPN12 | c.1785C>T p.L595= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as rs371650087; called by muse, mutect2, varscan2
- RABGAP1 | c.3209G>A p.*1070= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV65379640; called by muse, mutect2, varscan2
- RAPGEF1 | c.1998C>T p.D666= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs755518512, COSV100940621; called by muse, mutect2, varscan2
- RDH8 | c.936C>G p.L312= (on ENST00000651512; = p.L292= on NM_015725.4) | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV50676467; called by muse, mutect2, varscan2
- RGL1 | c.87C>T p.L29= (on ENST00000360851 / NM_001297672.2; = p.L64= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV100486946; called by muse, mutect2, varscan2
- RRP1 | c.819C>T p.I273= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV101513876; called by muse, mutect2, varscan2
- SH3BP4 | c.1089G>A p.P363= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs377177002, COSV60646006; called by muse, mutect2, varscan2
- SHISAL2A | c.270C>T p.I90= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV101284253; called by muse, mutect2, varscan2
- SLC26A6 | c.561C>T p.L187= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV50857792; called by muse, mutect2, varscan2
- SLC35G5 | c.283C>T p.L95= | Silent (SNP) | VAF 39/307 reads (13%) | catalogued as rs1278546850, COSV55314043, COSV99644327; called by muse, mutect2, varscan2
- SLC38A7 | c.1242C>T p.L414= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99543800; called by muse, mutect2, varscan2
- SLC49A4 | c.624C>T p.P208= | Silent (SNP) | VAF 24/157 reads (15%) | called by muse, mutect2, varscan2
- SMTNL2 | c.1369C>T p.L457= (on ENST00000389313 / NM_001114974.2; = p.L313= on NM_198501.3) | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as rs1177175087, COSV58807473; called by muse, mutect2, varscan2
- SPG7 | c.918C>T p.V306= | Silent (SNP) | VAF 8/95 reads (8%) | catalogued as COSV99244986; called by muse, mutect2
- SRSF6 | c.687G>C p.R229= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99719730; called by muse, mutect2, varscan2
- TACC2 | c.2310G>C p.S770= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100552487; called by muse, mutect2, varscan2
- TAS2R50 | c.588G>A p.L196= | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as rs1012733648, COSV101114948; called by muse, mutect2, varscan2
- TLL2 | c.2520G>A p.P840= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs755013110, COSV100780281, COSV100780320; called by muse, mutect2, varscan2
- TMBIM6 | c.453G>A p.L151= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV99920719; called by muse, mutect2, varscan2
- TMEM101 | c.69C>T p.L23= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs540158668, COSV99243837; called by muse, mutect2, varscan2
- TMEM266 | c.1125C>G p.L375= | Silent (SNP) | VAF 24/135 reads (18%) | catalogued as COSV101189577; called by muse, mutect2, varscan2
- TP53BP2 | c.942G>C p.L314= (on ENST00000343537 / NM_001031685.3; = p.L185= on NM_005426.2) | Silent (SNP) | VAF 34/177 reads (19%) | catalogued as COSV59072611; called by muse, varscan2
- TPH2 | c.249C>G p.L83= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as rs1318626178, COSV100422116; called by muse, mutect2
- TRIM65 | c.999G>A p.L333= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99485474; called by muse, varscan2
- TRPM5 | c.2391G>A p.K797= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as rs550081696, COSV99330180; called by muse, varscan2
- TRPM6 | c.5358C>T p.V1786= | Silent (SNP) | VAF 22/139 reads (16%) | catalogued as COSV100666455; called by muse, mutect2, varscan2
- TRPV4 | c.300G>A p.K100= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs370135765; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSR3 | c.938G>A p.*313= | Silent (SNP) | VAF 43/401 reads (11%) | catalogued as COSV99136255; called by muse, varscan2
- ULK1 | c.2817G>A p.L939= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100416930, COSV58856081; called by muse, mutect2, varscan2
- USP5 | c.729G>A p.P243= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs367936917; called by muse, mutect2, varscan2
- WASHC2A | c.1473C>T p.F491= | Silent (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
- WBP2NL | c.885C>T p.N295= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as rs751518880, COSV100173807; called by muse, mutect2, varscan2
- WNK1 | c.5317C>T p.L1773= (on ENST00000315939 / NM_018979.4; = p.L1526= on NM_014823.3) | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as COSV100267568; called by muse, mutect2, varscan2
- ZAN | c.837G>A p.V279= | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as rs1562918224, COSV100769793; called by muse, mutect2
- ZBTB32 | c.867C>G p.V289= | Silent (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- ZMYND15 | c.1680G>A p.Q560= (on ENST00000433935 / NM_001136046.3; = p.Q521= on NM_032265.2) | Silent (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2
- ZNF750 | c.1692G>A p.P564= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs758825441, COSV53960279; called by muse, mutect2, varscan2
- ZNF808 | c.2400C>T p.F800= | Silent (SNP) | VAF 26/231 reads (11%) | catalogued as COSV100707795, COSV63119513; called by muse, mutect2, varscan2
- ZUP1 | c.228G>A p.K76= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV100885093; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852226 G>A | 3'Flank (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- ANK3 | c.12596-269G>C | Intron (SNP) | VAF 17/156 reads (11%) | catalogued as COSV99780279; called by muse, mutect2, varscan2
- B4GALNT1 | c.*1318C>T | 3'UTR (SNP) | VAF 8/46 reads (17%) | catalogued as rs377400696; called by muse, mutect2, varscan2
- CDC37P1 | n.877G>A | RNA (SNP) | VAF 12/51 reads (24%) | catalogued as rs745597348; called by muse, mutect2, varscan2
- ELAVL4 | c.-2G>A | 5'UTR (SNP) | VAF 18/109 reads (17%) | catalogued as COSV100836756; called by muse, mutect2, varscan2
- FMN1 | c.2044-2631C>T | Intron (SNP) | VAF 11/88 reads (13%) | catalogued as COSV100568776, COSV57919896; called by muse, mutect2, varscan2
- LEF1 | c.*16G>T | 3'UTR (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99489657; called by muse, mutect2, varscan2
- MACF1 | c.15832-11657C>T | Intron (SNP) | VAF 6/132 reads (5%) | catalogued as COSV99244764; called by muse, mutect2
- MGAM | c.4618+335C>G | Intron (SNP) | VAF 10/33 reads (30%) | catalogued as COSV101527522; called by muse, mutect2, varscan2
- PAQR6 | c.*126G>A | 3'UTR (SNP) | VAF 24/208 reads (12%) | catalogued as COSV99431222; called by muse, mutect2, varscan2
- PIK3AP1 | c.1376-4502G>A | Intron (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100225832; called by muse, mutect2
- RNU7-174P | chr8:80559057 G>A | 5'Flank (SNP) | VAF 13/64 reads (20%) | catalogued as rs561533988; called by muse, mutect2, varscan2
- RPP38 | chr10:15096709 C>T | 5'Flank (SNP) | VAF 34/151 reads (23%) | called by muse, mutect2, varscan2
- USH1C | c.1285-7474G>C | Intron (SNP) | VAF 13/83 reads (16%) | catalogued as COSV99140222; called by muse, mutect2, varscan2
- ZNF655 | c.136+1207C>T | Intron (SNP) | VAF 8/19 reads (42%) | catalogued as COSV99402178; called by muse, mutect2, varscan2
